Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A7WJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A7WJ-01A (Primary Tumor).

[page 1 of 6]
Patient:

Hospital No:

Date of Birth:

Age/Sex:

Location:

Pathologist

Assistant:

Date of Procedure:

Date Received:

Accession Number:

Ordering M.D.:

Copies To:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. UTERUS, CERVIX, TUBES AND OVARIES (TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY):

- Endomyometrium:
- Endometrial adenocarcinoma, endometrioid type, FIGO Grade 2 (5.7 cm)
- Tumor invades through 11% of the myometrial thickness
- Lymphovascular invasion is indeterminate
- Adenomyosis
- Cervix:
- Squamous metaplasia
- Negative for tumor
- Serosa:
- Fibrinous adhesions
- Negative for tumor
- Right ovary:
- Atrophic
- Left ovary:
- Serous cyst (3.7 cm)
- Bilateral fallopian tubes:
- No specific pathologic change

ICD-O-3
Adenocarcinoma, endometrioid (No. 8880/3)
Site Endometrium C54.1
Jw 10/29/13

B. PELVIC LYMPH NODE #1, RIGHT (EXCISION):

- One lymph node, negative for tumor (0/1)

C. PELVIC LYMPH NODE #2, RIGHT (EXCISION):

- Fibroconnective tissue, negative for tumor
- No lymph node is identified

D. PA LYMPH NODE, RIGHT (EXCISION):

- One lymph node, negative for tumor (0/1)

E. PA LYMPH NODE, LEFT (EXCISION):

- Two lymph nodes, negative for tumor (0/2)

F. PELVIC LYMPH NODE, LEFT (EXCISION):

- One lymph node, negative for tumor (0/1)

SYNOPTIC REPORT:

Applies To:

Patient Case(s):

Copy For:

[page 2 of 6]
PATIENT:

ACCESSION #:

A : UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES
B : RIGHT PELVIC LN #1
C : RIGHT PELVIC LN #2
D : RIGHT PA LN
E : LEFT PA LN
F : LEFT PELVIC LN

Macroscopic

Procedure:	Total abdominal hysterectomy and bilateral salpingo-oophorectomy
Specimen Integrity:	Intact hysterectomy specimen
Lymph Node Sampling:	Pelvic lymph nodes Para-aortic lymph nodes

Microscopic

Histologic Type:	Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade:	FIGO grade II
Tumor Site:	Corpus Fundus Lower uterine segment
Tumor Size:	Dimensions: 5.7 x 3.8 x 1cm
Myometrial Invasion:	Invasion present Depth of invasion: 0.2cm Myometrial thickness: 1.7cm Less than 50% myometrial invasion
Involvement of Cervix:	No involvement
Extent of Involvement of Other Organs:	None
Margins:	Uninvolved by invasive carcinoma
Lymphovascular Invasion:	Indeterminate

Pathologic Staging (pTNM) AJCC 7th Edition 2010

Primary Tumor (pT):	pT1a : Tumor limited to endometrium or invades less than one-half of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
Number of pelvic lymph nodes examined:	2
Number of pelvic lymph nodes involved:	0
Number of para-aortic lymph nodes examined:	3
Number of para-aortic lymph nodes involved:	0

HISTORY:
Uterine cancer, hepatitis B

SURGICAL PATHOLOGY REPORT

[page 3 of 6]
PATIENT:

ACCESSION #:

MICROSCOPIC FINDINGS:

See diagnosis.

GROSS:

A. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES

Patient name, label: designated "uterus, cervix, bilateral tubes and ovaries"

Specimen type: Total hysterectomy and bilateral salpingo-oophorectomy
Received: Fresh for intraoperative consultation and subsequently fixed in formalin

Specimen integrity: Previously incised

Specimen weight: 76 grams

Specimen size:

Overall uterine dimensions: 7.0 x 5.0 x 4.0 cm
Cervix alone: 2.5 cm in length, up to 3.0 cm in diameter
Vaginal cuff: Absent
Endometrial cavity: 3.8 cm in width, 4.0 cm in length
Endometrial thickness: Ranges from 0.1 to 1.0 cm
Myometrial thickness: Ranges from 0.7 to 1.2 cm
Left parametrium: Absent
Right parametrium: Absent
Left ovary: 3.7 x 2.2 x 1.3 cm
Left fallopian tube: 2.0 cm in length, 0.2 to 0.4 cm in diameter with a 0.1 cm maximum luminal diameter, fimbria not identified
Right ovary: 2.1 x 0.8 x 0.7 cm
Right fallopian tube: 2.7 cm in length, 0.2 to 0.4 cm in diameter with a 0.1 cm maximum luminal diameter, fimbria not identified

Pathologic findings:

Tumor:

Location: Uterine fundus, uterine corpus (anterior and posterior), lower uterine segment (anterior and posterior)
Size: 5.7 x 3.8 x 1.0 cm
Color: Pale tan
Consistency: Soft and friable
Configuration: Papillary, fungating
Myometrial invasion: Present and involves up to 0.7 cm of the wall thickness where the wall is up to 1.8 cm
Grossly evident vascular invasion: Absent
Uterine serosal involvement: Absent
Cervical involvement: Absent
Parametrial involvement: Absent
Left ovary: Uninvolved by metastatic tumor
Left fallopian tube: Uninvolved by metastatic tumor
Right ovary: Uninvolved by metastatic tumor
Right fallopian tube: Uninvolved by metastatic tumor

Other Findings:

Non-neoplastic endometrium: Unremarkable
Endometrial polyp(s): Not identified
Leiomyoma(s): Not identified
Other myometrial lesion(s): Not identified
Uterine serosa: Unremarkable
Cervix: Unremarkable

[page 4 of 6]
PATIENT:**ACCESSION #:**

Vaginal cuff:	Unremarkable
Left ovary:	Shows that the left ovary appears to be entirely replaced with a unilocular cyst. The cyst wall is smooth and no papillary excrescences are identified.
Left fallopian tube:	Unremarkable
Right ovary:	Unremarkable
Right fallopian tube:	Unremarkable
Additional findings:	None

A portion of the tumor, right ovary and right fallopian tube are released to _____ per standard operating procedure. Representative sections of the remaining tissue are submitted.

Slide key:

- A1. Anterior cervix - 1
- A2. Posterior cervix - 1
- A3, A4. Anterior lower uterine segment with tumor - 1 each
- A5, A6. Posterior lower uterine segment with tumor - 1 each
- A7, A8. Anterior uterine corpus with tumor - 1 each
- A9, A10. Posterior uterine corpus with tumor - 1 each
- A11. Uterine fundus with tumor - 1
- A12. Right ovary, entirely submitted - 2
- A13. Proximal, mid, distal end of right fallopian tube - 3
- A14. Left ovary - 3
- A15. Proximal, mid, distal end of left fallopian tube - 3

B. RIGHT PELVIC LN #1

Patient name, label:	" _____ , designated "right pelvic LN #1"
Specimen type:	Lymph node sampling
Received:	In formalin
Specimen contents:	Adipose tissue and lymph nodes
Number of pieces of tissue:	Four
Size of specimen:	2.8 x 2.2 x 0.7 cm in aggregate
Number of lymph nodes:	One
Size of lymph nodes:	1.0 x 0.8 x 0.5 cm in maximum dimension
Tumor:	No gross tumor is seen.
Additional findings:	None

The lymph node is entirely embedded.

Slide key:

- B1. One lymph node, bisected - 2

C. RIGHT PELVIC LN #2

Patient name, label:	_____ , designated "right pelvic LN #2"
Specimen type:	Excision
Received:	In formalin
Specimen contents:	Adipose tissue
Number of pieces of tissue:	One
Size of specimen:	1.9 x 0.6 x 0.3 cm
Number of lymph nodes:	0
Tumor:	No gross tumor is seen.
Additional findings:	None

Entirely submitted.

[page 5 of 6]
PATIENT:

ACCESSION #:

Slide key:

C1. 1

D. RIGHT PA LN

Patient name, label:

designated "right PA LN"

Specimen type:

Lymph node sampling

Received:

In formalin

Specimen contents:

Adipose tissue and lymph nodes

Number of pieces of tissue:

Two

Size of specimen:

1.2 x 0.9 x 0.5 cm

Number of lymph nodes:

One

Size of lymph nodes:

0.9 x 0.7 x 0.6 cm

Tumor:

No gross tumor is seen.

Additional findings:

None

The lymph node is entirely submitted.

Slide key:

D1. One lymph node - 1

E. LEFT PA LN

Patient name, label:

designated "left PA LN"

Specimen type:

Lymph node sampling

Received:

In formalin

Specimen contents:

Adipose tissue and lymph node

Number of pieces of tissue:

Two

Size of specimen:

2.2 x 0.8 x 0.4 cm in aggregate

Number of lymph nodes:

One

Size of lymph nodes:

1.4 cm in maximum dimension

Tumor:

No gross tumor is seen.

Additional findings:

None

Entirely submitted.

Slide key:

E1. One possible lymph node - 1

E2. Additional tissue - 1

F. LEFT PELVIC LN

Patient name, label:

designated "left pelvic LN"

Specimen type:

Lymph node sampling

Received:

In formalin

Specimen contents:

Adipose tissue and lymph node

Number of pieces of tissue:

Three

Size of specimen:

2.8 x 2.4 x 0.9 cm

Number of lymph nodes:

One

Size of lymph nodes:

1.1 x 0.8 x 0.7 cm in maximum dimension

Tumor:

No gross tumor is seen.

Additional findings:

None

The lymph node is entirely submitted.

Slide key:

SURGICAL PATHOLOGY REPORT

[page 6 of 6]
PATIENT:

ACCESSION #:

F1. One lymph node, bisected - 2

Gross dictated by

INTRAOPERATIVE CONSULTATION:
OPERATIVE CALL
OPERATIVE CONSULT (GROSS):

A. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES:

- Grossly the lesion is in the endometrium. It is compatible with the patient's diagnosis of endometrial carcinoma.
- Portions of the tumor, right ovary and right fallopian tube are procured for tissue bank

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by those
immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Page 6 of 6

Source: NCI Genomic Data Commons file 49a24bae-880d-45d2-aa9a-988d8a5d782e (TCGA-A5-A7WJ.402A6ED4-B9EC-43A0-B47C-A0B95282678D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).